Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7821, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7821-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Right pelvic lymph nodes, excision:

Two lymph nodes, negative for metastatic disease.
Frozen section diagnosis confirmed.

B. Right and left pelvic lymph nodes, excision:

Two of five lymph nodes positive for metastatic carcinoma.

C. Prostate, prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 71.5 grams, 4.8 x 4.8 x 4.8 cm.
3. Tumor quantitation: Tumor occupies approximately 75% of prostate volume.
4. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 8/10.
5. Extraprostatic extension: Not definitively seen.
6. Seminal vesicle involvement: Present.
7. Lymphovascular space invasion: Present.
8. High grade PIN: Present.

Surgical Margin Status:

1. Tumor extends to inked apex and base margins as well as focally to the inked surface most prominently the left anterior portion.

Lymph Node Status:

1. See parts A, B.

Other:

1. pTNM stage: pT3b N1.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right pelvic lymph node with frozen section
- B. Right and left pelvic lymph nodes
- C. Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three containers labeled with the patient's name,

Container A is additionally labeled "#1" and contains a 1.5 x 1.0 x 1.0 cm, yellow-tan, firm, fatty nodule consistent with possible lymph node. This node is bisected and submitted for frozen section. The residual is entirely resubmitted for permanent section in cassette A1 labeled On further palpation, an additional nodule is identified possibly consistent with lymph node, 1.1 cm in greatest dimension. All remaining tissue including this nodule is submitted in cassette A2.

Container B is additionally labeled "right and left pelvic lymph nodes" and contains a 5.7 x 3.0 x 2.0 cm aggregate of yellow-tan fibrofatty soft tissue. On

palpation, five firm fatty possible lymph nodes are identified ranging from 0.4 up to 3.5 cm in greatest dimension. They are entirely submitted in cassettes B1-4 labeled designated as follows: B1 three whole possible lymph node; B2 one whole possible bisected lymph node; B3-4 one whole possible quartersected lymph node.

Container C is additionally labeled "prostate" and contains a 71.5 gm, 4.8 x 4.8 x 4.8 cm prostate received with attached bilateral adnexa having overall dimensions of 4.0 x 2.8 x 1.5 cm. The prostatic capsule is pink-tan and shaggy. The specimen is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned from apex to base to reveal a pink-tan, focally cystic cut surface with periurethral nodularity. The cut surface features diffuse induration located primarily on the left half, however a well defined mass is not identified. Representative sections are submitted in cassettes C1-18 labeled designated as follows: 1 right prostate/seminal vesicle junction; 2 left prostate/seminal vesicle junction; 3-4 apical margin, perpendicular, 5-6 base margin, perpendicular; 7-9 right anterior, apex to base; 10-12 right posterior, apex to base; 13-15 left anterior, left apex to base; 16-18 left posterior, apex to base. Additionally, a yellow, green and blue cassettes are submitted for genomics research, each labeled

OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS PART A: Tumor not seen

Source: NCI Genomic Data Commons file a152c3fe-d3f2-428b-8a12-7251a2bc1180 (TCGA-HC-7821.89C7A876-D606-48A6-9672-7CB976058EBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).